Gene-level copy-number profile of tumor specimen TCGA-13-0807-01B from TCGA case TCGA-13-0807, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.5 years (19,890 days).
Specimen TCGA-13-0807-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.be50c3a9-64cd-4044-a3db-de08e59d9e64.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0807-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/26c8439a-6bba-483f-8439-c7af03a205ee

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,552; copy number 2: 17,083; copy number 3: 28,814; copy number 4: 9,121; copy number 5: 1,163; copy number 6: 920; copy number 7: 268; copy number 8: 332; copy number 9: 157; copy number 10: 181; copy number 11: 36; copy number 12: 4; copy number 14: 32; copy number 15: 82; copy number 16: 18; copy number 17: 19; copy number 18: 7; copy number 19: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0807-01B-02D-0399-01): tumor purity 0.77, ploidy 3.03, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:80,157,232–80,247,514, 1 gene (within-gene range 0–2): PARD6G.
- chr18:80,183,680–80,202,992, 1 gene: AC139100.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,142 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–148,288,951, 47 genes, copy number 9–11 (within-gene range 6–11): AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3.
- chr1:148,295,180–148,344,638, 6 genes, copy number 9: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21.
- chr1:150,255,095–152,445,456, 120 genes, copy number 10 (broad region; genes not listed).
- chr1:152,737,518–153,567,890, 52 genes, copy number 8: LCEP2, LCEP1, KPRP, LCE1F, LCE1E, LCE1D, LCE1C, LCE1B, LCE1A, LCE6A, AL162596.1, SMCP, IVL, LINC01527, SPRR5, SPRR4, SPRR1A, SPRR3, AL356867.2, AL356867.1, SPRR1B, SPRR2D, SPRR2A, SPRR2B, SPRR2E, SPRR2F, SPRR2C, SPRR2G, AL161636.1, LELP1, PRR9, AL161636.2, LORICRIN, PGLYRP3, PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7, RN7SL44P, BX470102.1, S100A6, S100A5, S100A4, S100A3, S100A2.
- chr1:154,924,740–155,050,930, 15 genes, copy number 9: PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1.
- chr3:75,906,695–77,649,964, 1 gene, copy number 8 (within-gene range 3–8): ROBO2.
- chr3:76,434,018–77,317,598, 3 genes, copy number 8: CAP1P1, RNU6-386P, VDAC1P7.
- chr3:80,602,716–84,051,419, 21 genes, copy number 8: AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1.
- chr3:84,691,681–84,692,591, 1 gene, copy number 8: AC117482.1.
- chr3:86,125,216–87,158,363, 9 genes, copy number 8–12 (within-gene range 3–12): AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506.
- chr8:32,026,210–32,139,495, 1 gene, copy number 8 (within-gene range 1–8): NRG1-IT1.
- chr8:34,784,028–34,865,364, 1 gene, copy number 7 (within-gene range 1–7): LINC01288.
- chr8:35,080,592–35,093,509, 1 gene, copy number 8: AC099685.1.
- chr8:40,298,697–40,520,158, 3 genes, copy number 9: SIRLNT, AC105999.1, AC010857.1.
- chr8:50,490,795–63,478,745, 188 genes, copy number 7–10 (broad region; genes not listed).
- chr9:14,475–13,034,326, 170 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:31,111,652–37,576,384, 84 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr12:45,475,520–46,972,155, 22 genes, copy number 11–15: AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1.
- chr12:54,353,661–54,497,688, 2 genes, copy number 7 (within-gene range 2–7): AC079313.2, AC079313.1.
- chr12:54,395,261–56,190,284, 96 genes, copy number 7 (broad region; genes not listed).
- chr12:63,055,275–63,272,336, 4 genes, copy number 10: RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69.
- chr12:64,713,445–65,966,291, 26 genes, copy number 9–16 (within-gene range 2–16): GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1.
- chr12:78,352,519–78,540,675, 3 genes, copy number 10: AC128707.1, AC130415.1, AC079362.1.
- chr13:43,023,203–44,809,630, 35 genes, copy number 7–14: DNAJC15, LINC00400, AL138709.1, ENOX1, RPL36P19, ENOX1-AS2, ENOX1-AS1, AL161714.1, AL162713.2, AL162713.1, CCDC122, AL512506.1, LACC1, AL512506.3, AL512506.2, NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1, AL138960.1, SERP2, TUSC8, TSC22D1, AL138960.2, AL139184.1, TSC22D1-AS1, SMARCE1P5, LINC00407, AL356515.1, LINC00330.
- chr13:50,812,988–50,910,764, 2 genes, copy number 9: RNA5SP28, RNASEH2B-AS1.
- chr18:22,586,465–30,714,286, 108 genes, copy number 8–18 (broad region; genes not listed).
- chr18:31,058,840–32,131,561, 36 genes, copy number 8–17: DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2.
- chr18:32,176,050–32,176,168, 1 gene, copy number 8: RNA5SP453.
- chr19:29,775,504–31,147,981, 21 genes, copy number 9–19: AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1.
- chr19:31,167,457–31,225,143, 1 gene, copy number 9: LINC01791.
- chr19:39,125,770–40,122,168, 62 genes, copy number 15 (within-gene range 3–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,552. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
